Gene-level copy-number profile of tumor specimen TARGET-40-PASNZV-01A from TARGET case TARGET-40-PASNZV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.3 years (5,947 days).
Specimen TARGET-40-PASNZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.d6386fbe-ce13-5efc-acec-5b793de3af72.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASNZV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate.
https://portal.gdc.cancer.gov/files/2c8597fd-a8d3-49d4-b373-44ba43b2a744

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 635; copy number 1: 28,470; copy number 2: 25,757; copy number 3: 3,289; copy number 4: 1,530; copy number 5: 293; copy number 6: 110; copy number 7: 96; copy number 8: 13; copy number 10: 23.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:158,972,871–159,000,202, 1 gene (within-gene range 0–1): RSPH3.
- chr10:22,534,854–28,941,910, 109 genes (within-gene range 0–1) (broad region; genes not listed).
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr17:40,977,716–40,987,135, 1 gene (within-gene range 0–2): KRT40.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,346 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,908,098–22,266,300, 19 genes, copy number 3: AL590556.1, AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1, MIR4418.
- chr1:143,541,768–174,090,474, 1,101 genes, copy number 4–10 (broad region; genes not listed).
- chr1:175,877,343–176,447,919, 13 genes, copy number 4: LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr1:177,170,958–181,238,604, 82 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:223,947,605–224,035,056, 6 genes, copy number 3: CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2.
- chr1:227,482,253–228,416,861, 45 genes, copy number 4: AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77, ZNF678, FAM133FP, ZNF847P, SNAP47, JMJD4, SNAP47-AS1, AL731702.1, PRSS38, WNT9A, MIR5008, CICP26, SEPTIN14P17, WNT3A, LINC02809, ARF1, MIR3620, C1orf35, MRPL55, FAM96AP2, AL136379.1, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57, OBSCN-AS1, OBSCN, AL353593.1, AL353593.2, AL353593.3, AL670729.3, AL670729.2, TRIM11, AL670729.1, MIR6742, AL139288.1, TRIM17.
- chr1:236,348,257–236,502,915, 2 genes, copy number 3: EDARADD, ENO1P1.
- chr1:240,341,385–241,357,230, 18 genes, copy number 3–4 (within-gene range 1–4): Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr2:39,436,530–47,663,146, 135 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:50,829,442–54,972,025, 46 genes, copy number 3 (within-gene range 2–3): AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P.
- chr2:85,133,392–95,668,727, 303 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr4:131,720,260–133,263,115, 18 genes, copy number 3: RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1, ELL2P2, AC114741.1, LINC01256, AARS1P1, AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10, AC108052.1.
- chr4:134,383,467–134,817,289, 2 genes, copy number 3: LINC02462, AC093722.1.
- chr4:135,792,384–136,553,739, 9 genes, copy number 3: AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3, AC093875.1.
- chr4:143,760,399–143,912,053, 3 genes, copy number 3–4: AC104090.1, GYPE, AC093890.1.
- chr4:155,342,658–160,818,869, 83 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:167,607–24,809,798, 402 genes, copy number 3 (broad region; genes not listed).
- chr6:39,104,063–42,194,956, 78 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:42,727,234–60,546,660, 294 genes, copy number 3 (broad region; genes not listed).
- chr8:4,317,388–4,635,654, 3 genes, copy number 3: AC027251.1, AC010941.1, AC022068.1.
- chr8:62,191,088–63,086,053, 11 genes, copy number 4 (within-gene range 2–4): AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA.
- chr8:64,456,198–64,973,848, 10 genes, copy number 3: AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1.
- chr8:94,487,689–95,156,685, 29 genes, copy number 3: VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:100,380,486–131,040,909, 411 genes, copy number 3–8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:132,507,962–138,083,657, 63 genes, copy number 4–6 (within-gene range 1–6) (broad region; genes not listed).
- chr9:78,589,158–83,069,143, 46 genes, copy number 3: AL592221.1, MTND2P8, KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1.
- chr9:87,553,454–93,858,340, 140 genes, copy number 3–4 (broad region; genes not listed).
- chr11:167,784–915,058, 69 genes, copy number 3 (broad region; genes not listed).
- chr11:1,464,582–1,984,522, 33 genes, copy number 4: AC091196.1, MOB2, DUSP8, KRTAP5-AS1, KRTAP5-1, KRTAP5-2, KRTAP5-3, KRTAP5-4, KRTAP5-5, AP006285.1, FAM99A, FAM99B, LINC02708, KRTAP5-6, IFITM10, AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.5, AC068580.2, RPL36AP39, AC139143.1, SYT8, TNNI2, LSP1, MIR4298, AC051649.1, MIR7847, PRR33, LINC01150, TNNT3, MRPL23.
- chr11:2,444,684–3,166,739, 23 genes, copy number 3–4 (within-gene range 2–4): KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4, AC021424.2, COX6CP18, KCNQ1-AS1, KCNQ1DN, AC013791.1, CDKN1C, SLC22A18AS, SLC22A18, PHLDA2, NAP1L4, SNORA54, AC131971.1, CARS1, CARS1-AS1, RNU1-91P, AC108448.3, AC108448.2, OSBPL5.
- chr11:8,679,089–8,714,759, 4 genes, copy number 4: AC091053.2, RPL27A, SNORA3A, SNORA3B.
- chr11:9,019,476–9,314,636, 9 genes, copy number 4 (within-gene range 2–4): SCUBE2, AC079296.2, MIR5691, KRT8P41, DENND5A, AP006259.1, Metazoa_SRP, TMEM41B, PRR13P2.
- chr11:44,885,903–45,286,341, 7 genes, copy number 3: TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1.
- chr11:95,768,953–135,075,908, 780 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr15:25,062,333–25,083,679, 13 genes, copy number 4: SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15, SNORD116-16, SNORD116-17.
- chr16:66,469,812–68,229,259, 113 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr18:27,225,742–50,266,495, 301 genes, copy number 3 (within-gene range 1–4) (broad region; genes not listed).
- chr18:65,606,079–67,899,619, 20 genes, copy number 3: AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2.
- chr19:22,243,254–22,261,335, 2 genes, copy number 5: AC073539.1, AC073539.3.
- chr22:16,405,330–26,780,893, 587 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26,060. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
